Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6433, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6433-01A (Primary Tumor).

[page 1 of 4]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) CONTENTS SUBMENTAL TRIANGLE:
Three lymph nodes, no tumor present (0/3).
- (B) CONTENTS RIGHT LEVEL 1:
Two lymph nodes, no tumor present (0/2).
- (C) COMPOSITE RESECTION, TOTAL LARYNGECTOMY, TOTAL GLOSSECTOMY:
INVASIVE SQUAMOUS CARCINOMA – Poorly-differentiated/basaloid
Tumor Features:
Size: 4 cm in largest dimension
Invasion: Present, depth 0.65 cm
Tumor Border: Broad nests
Perineural Invasion: Absent
Vascular Invasion: Absent
Bone / Cartilage Invasion: Tumor invades epiglottic cartilage.
- (D) RIGHT DEEP PARAPHARYNGEAL:
SQUAMOUS CARCINOMA PRESENT
- (E) RIGHT PARAPHARYNGEAL:
SQUAMOUS CARCINOMA PRESENT.
- (F) LEFT PARAPHARYNGEAL:
Squamous mucosa with mild dysplasia.
No invasive carcinoma present.
- (G) RIGHT SUPERIOR PARAPHARYNGEAL:
SQUAMOUS CARCINOMA PRESENT
- (H) LEFT SUPERIOR PARAPHARYNGEAL:
Squamous mucosa, no tumor present.
- (I) RIGHT RETROMOLAR TRIGONE:
Squamous mucosa, no tumor present.
- (J) RIGHT LATERAL PIRIFORM SINUS:
Squamous mucosa, no tumor present.
- (K) LEFT LATERAL PIRIFORM SINUS:
Squamous mucosa, no tumor present.
- (L) RIGHT UPPER ESOPHAGUS:

[page 2 of 4]
[REDACTED]

Squamous mucosa, no tumor present.

(M) LEFT UPPER ESOPHAGUS:

Squamous mucosa, no tumor present.

(N) POSTERIOR CRICOID:

Squamous mucosa, no tumor present.

(O) RIGHT PARAPHARYNGEAL:

INVASIVE SQUAMOUS CARCINOMA, EXTENDING TO INKED TISSUE EDGE

(P) RIGHT PARAPHARYNGEAL:

Squamous mucosa, negative for tumor. (See comment)

(Q) RIGHT SUPERIOR PARAPHARYNGEAL SOFT TISSUE:

Denuded squamous mucosa with no tumor present.

[REDACTED]

COMMENT

The intact tissue sections in part P are negative for invasive tumor. The overall findings favor an interpretation of no tumor present.

GROSS DESCRIPTION

(A) CONTENTS SUBMENTAL TRIANGLE – A portion of yellow-tan adipose tissue measuring 3.5 x 2.1 x 1 cm. Five potential lymph nodes are found, ranging in greatest dimension from 0.3 to 0.6 cm. No tumor is seen grossly.

SECTION CODE: A1, five potential lymph nodes; A2, remainder of specimen. [REDACTED]

(B) CONTENTS RIGHT LEVEL 1 – A portion of adipose tissue measuring 4.1 x 3 x 1.5 cm. This measurement includes the salivary gland, which measures 3 x 1 x 1 cm. Three potential lymph nodes are found, ranging in size from 0.5 to 1 cm in greatest dimension. The salivary gland is serially sectioned and appears unremarkable.

SECTION CODE: B1, three potential lymph nodes (one bisected, inked in blue); B2, adipose tissue from specimen (all adipose tissue is submitted); B3, representative portion of salivary gland [REDACTED]

*FS/DX: DETACHED FRAGMENT OF CARCINOMA IN FIBRIN (? CONTAMINANT). [REDACTED]

(C) COMPOSITE RESECTION, TOTAL LARYNGECTOMY, TOTAL GLOSSECTOMY – The entire tongue (8 x 7 x 3.5 cm) and attached larynx with attached first trachea ring (8 x 5 x 4 cm). There is an ulcerated lesion (4 x 3 cm), obliterating the base of the tongue, epiglottis, and pharynx bilaterally. An ill-defined tumor associated with the ulcer invades the base of tongue, hyoid bone, left inferior (ventral) surface of the tongue and soft tissue/ skeletal muscle deep to tongue at the neck. No tumor is identified within the larynx. Thyroid gland is not present.

SECTION CODE: C1, C2, midline- tumor with base of tongue; C3, ulcerated region left; C4, ulcerated region right; C5, C6, ulceration with deep skeletal muscle extending to neck/chin region; C7, ulcerated tumor with epiglottis; C8, C9, additional ulceration bed; C10, para- laryngeal soft tissue; C11, left transglottic section; C12, right transglottic section. [REDACTED]

C13, representative section of hyoid bone for decalcification. [REDACTED]

[page 3 of 4]
- (D) RIGHT DEEP PARAPHARYNGEAL – A 0.5 x 0.5 x 0.4 cm fragment of mucosa entirely frozen in D. [REDACTED]
*FS/DX: SQUAMOUS CELL CARCINOMA. [REDACTED]
- (E) RIGHT PARAPHARYNGEAL - Soft tissue (1.1 x 0.3 x 0.2 cm). Entirely frozen as E. [REDACTED]
*FS/DX: SQUAMOUS CELL CARCINOMA. [REDACTED]
- (F) LEFT PARAPHARYNGEAL – Soft tissue (1.1 x 0.3 x 0.2 cm). Entirely frozen as F. [REDACTED]
*FS/DX: MILD SQUAMOUS DYSPLASIA, NO INVASIVE CARCINOMA. [REDACTED]
- (G) RIGHT SUPERIOR PARAPHARYNGEAL - Soft tissue (1.8 x 0.4 x 0.4 cm). Entirely frozen as G. [REDACTED]
*FS/DX: SQUAMOUS CELL CARCINOMA. [REDACTED]
- (H) LEFT SUPERIOR PARAPHARYNGEAL – Soft tissue (1.1 x 0.3 x 0.2 cm). Entirely frozen as H. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]
- (I) RIGHT RETROMOLAR TRIGONE – Soft tissue (1.1 x 0.3 x 0.2 cm). Entirely frozen as I. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]
- (J) RIGHT LATERAL PIRIFORM SINUS – Soft tissue (1.0 x 0.8 x 0.3 cm). Entirely frozen as J. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]
- (K) LEFT LATERAL PIRIFORM SINUS – Soft tissue (1.0 x 0.3 x 0.2 cm). Entirely frozen as K. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]
- (L) RIGHT UPPER ESOPHAGUS – Soft tissue (0.5 x 0.2 x 0.2 cm). Entirely frozen as L. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]
- (M) LEFT UPPER ESOPHAGUS – Soft tissue (0.8 x 0.2 x 0.2 cm). Entirely frozen as M. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]
- (N) POSTERIOR CRICOID – Soft tissue (1.2 x 0.3 x 0.2 cm). Entirely frozen as N. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]
- (O) RIGHT PARAPHARYNGEAL, INK ON PT SIDE – A portion of irregularly shaped pink-tan soft tissue (2.7 x 1.3 x 0.5 cm). The area indicated as PT side is re-inked in blue and specimen is perpendicularly sectioned through this area and submitted in its entirety as O. [REDACTED]
- (P) RIGHT PARAPHARYNGEAL – Soft tissue (1.1 x 0.3 x 0.3 cm). Entirely frozen as [REDACTED]
*FS/DX: DETACHED FRAGMENT OF CARCINOMA IN FIBRIN (? CONTAM [REDACTED])
- (Q) RIGHT SUPERIOR PARAPHARYNGEAL SOFT TISSUE – Soft tissue (1.2 x 0.4 x 0.3 cm). Entirely frozen as Q. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]

CLINICAL HISTORY

Tongue cancer

SNOMED CODES

T-24100, T-53131, T-C4200, M-80703 "Some tests reported here may have been developed and performance characteristics determined by [REDACTED] and Laboratory Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by: [REDACTED] [REDACTED] [REDACTED]

[page 4 of 4]
ADDENDUM

This modified report is being issued to provide additional information/results.

COMMENT

Additional sections reviewed following decalcification.

In part C, the tumor also invades hyoid bone.

Entire report and diagnosis completed by:

Source: NCI Genomic Data Commons file de4de4e5-0cdf-43f8-8c20-0266f523a524 (TCGA-CV-6433.713C393C-C32E-4AC9-9E34-E985F7E1BA7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).